Somatic mutation profile of tumor specimen TCGA-28-2514-01A (aliquot TCGA-28-2514-01A-02D-1494-08) from TCGA case TCGA-28-2514, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 45.8 years (16,737 days).
Specimen TCGA-28-2514-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6ba96d8-8336-4caa-8909-e604e16fc14e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-2514-10A (Blood Derived Normal), aliquot TCGA-28-2514-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4df06fc-288f-4ba3-a17b-8f278bcff1f6

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, Nonsense Mutation 3, Splice Site 3, In Frame Ins 1, Intron 1, In Frame Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.749C>G p.P250R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265851804, COSV55602632; called by muse, mutect2, varscan2
- AFM | c.1603A>C p.M535L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56922562; called by muse, mutect2, varscan2
- ANKS3 | c.868+1G>A p.X290_splice | Splice Site (SNP) | VAF 14/264 reads (5%) | catalogued as rs1267163643, COSV58512244; called by muse, mutect2
- ARFGEF3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1326151522, COSV52472440; called by muse, mutect2, varscan2
- CAMK4 | c.851A>C p.D284A | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56685004; called by muse, mutect2, varscan2
- CNGB1 | c.3544G>A p.D1182N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs868226949, COSV51906019; called by muse, mutect2, varscan2
- CREBBP | c.5986G>A p.A1996T | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs1302332843, COSV52143090; called by muse, mutect2, varscan2
- DLK1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs754418195, COSV57990874; called by muse, mutect2, varscan2
- DPP10 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs1055873408, COSV59686211; called by muse, mutect2, varscan2
- EIF4H | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56083743; called by muse, mutect2, varscan2
- ETNPPL | c.1303+2T>C p.X435_splice | Splice Site (SNP) | VAF 31/100 reads (31%) | catalogued as COSV56597865, COSV99625260; called by muse, mutect2, varscan2
- FBLN2 | c.2686G>A p.G896S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.164); catalogued as rs1055157175, COSV55488310; called by muse, mutect2, varscan2
- GRM8 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs760631675, COSV58874971; called by muse, mutect2, varscan2
- IDO1 | c.775T>A p.F259I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53716561; called by muse, mutect2
- IL26 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 109/292 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs749146583, COSV57490251; called by muse, mutect2, varscan2
- KIR2DS4 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 196/665 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.067); catalogued as rs760743437; called by muse, mutect2, varscan2
- KRT39 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs762707953, COSV62918131; called by muse, mutect2, varscan2
- LRRC66 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 148/324 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1426002150, COSV58637149; called by muse, mutect2, varscan2
- MIPEP | c.603G>A p.K201= | Splice Region (SNP) | VAF 85/263 reads (32%) | catalogued as rs1192020026, COSV66302104; called by muse, mutect2, varscan2
- ONECUT2 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs1312900705, COSV72203894; called by muse, mutect2, varscan2
- OR2T2 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs759070015; called by mutect2, varscan2
- PDZD3 | c.550A>T p.S184C (on ENST00000531114; = p.S118C on NM_024791.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV52710345; called by muse, mutect2, varscan2
- PILRA | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52202741; called by muse, mutect2, varscan2
- PLCH2 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1221516458, COSV53946971; called by muse, mutect2, varscan2
- PRIM1 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57718297; called by muse, mutect2, varscan2
- PRR27 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs577881430, COSV60641128; called by muse, mutect2, varscan2
- RAD21 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52064665; called by muse, mutect2, varscan2
- RBM47 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778126567, COSV55942848; called by muse, mutect2, varscan2
- RNASET2 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV50352330; called by muse, varscan2
- SERPINA7 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 119/142 reads (84%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59665958, COSV59666149; called by muse, mutect2, varscan2
- SIN3A | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1196648474, COSV64581745, COSV64584116; called by muse, mutect2, varscan2
- STAU1 | c.724G>A p.A242T (on ENST00000371856 / NM_001319135.1; = p.A161T on NM_004602.3) | Missense Mutation (SNP) | VAF 208/478 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61460360; called by muse, mutect2, varscan2
- SULT1B1 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs374341407; called by muse, mutect2, varscan2
- SUV39H2 | c.213G>T p.W71C (on ENST00000354919 / NM_001193424.2; = p.W11C on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57955794; called by muse, mutect2
- SYNPO2 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV61118658; called by muse, mutect2, varscan2
- SYTL2 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 215/492 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100314200, COSV60364503; called by muse, mutect2, varscan2
- TNFSF14 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 97/321 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs772753769, COSV55590283; called by muse, mutect2, varscan2
- TRAT1 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 82/240 reads (34%) | catalogued as rs148894492; called by muse, mutect2, varscan2
- ZNF337 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 37/438 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV53320931; called by muse, mutect2
- ZNF98 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV100757423; called by muse, mutect2, varscan2
- ADAM29 | c.2077_2079dup p.C693dup | In Frame Ins (INS) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- APC2 | c.3196dup p.S1066Ffs*24 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- ARHGEF7 | c.917+3_917+6del p.X306_splice (on ENST00000375741 / NM_001113511.2; = p.X128_splice on NM_003899.5 and 5 other RefSeq transcripts) | Splice Site (DEL) | VAF 26/94 reads (28%) | called by pindel, varscan2
- MKI67 | c.8157_8165del p.S2719_K2721del | In Frame Del (DEL) | VAF 98/143 reads (69%) | called by mutect2, pindel, varscan2
- ABCA13 | c.11988C>T p.T3996= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs199785430; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4029C>T p.L1343= | Silent (SNP) | VAF 52/147 reads (35%) | catalogued as COSV63247681; called by muse, mutect2, varscan2
- CELF5 | c.1359C>T p.S453= | Silent (SNP) | VAF 47/165 reads (28%) | catalogued as rs372894450; called by muse, mutect2, varscan2
- IFT80 | c.450G>A p.V150= | Silent (SNP) | VAF 112/299 reads (37%) | catalogued as COSV58453118; called by muse, mutect2, varscan2
- LDLR | c.981C>T p.H327= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs1060499933, COSV52946340; called by muse, mutect2, varscan2
- NLRP2 | c.2016C>T p.D672= | Silent (SNP) | VAF 73/240 reads (30%) | catalogued as rs374613201; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.340C>T p.L114= (on ENST00000374531 / NM_001037293.2; = p.L112= on NM_007203.5) | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs1261312617, COSV57133902; called by muse, mutect2, varscan2
- PCDHB7 | c.873G>T p.T291= | Silent (SNP) | VAF 83/224 reads (37%) | catalogued as rs782276991, COSV50825293; called by muse, varscan2
- PSMG3 | c.12G>T p.T4= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV52921020; called by muse, mutect2
- PTPRH | c.3180G>A p.P1060= | Silent (SNP) | VAF 94/341 reads (28%) | catalogued as rs769586690, COSV54750776; called by muse, mutect2, varscan2
- SLC9A4 | c.570C>T p.D190= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs755300636, COSV54835828; called by muse, mutect2, varscan2
- TNFSF14 | c.387C>T p.H129= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs147375196; called by muse, mutect2, varscan2
- PTPRN2 | c.2783+2202G>A | Intron (SNP) | VAF 61/146 reads (42%) | catalogued as COSV101153307; called by muse, mutect2, varscan2
